Gene-level copy-number profile of tumor specimen TCGA-AG-A020-01A from TCGA case TCGA-AG-A020, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.1 years (20,851 days).
Specimen TCGA-AG-A020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.6e8817aa-b2c4-4549-85ec-62ab05d4e586.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A020-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe2fb583-4226-45cf-a838-bd7775a2a4f1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 9; copy number 2: 6,676; copy number 3: 1,720; copy number 4: 46,984; copy number 5: 607; copy number 7: 2,538; copy number 8: 88; copy number 9: 13; copy number 10: 942; copy number 14: 237; copy number 16: 2; copy number 18: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A020-01A-21D-A080-01): tumor purity 0.87, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,196 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:127,997,597–128,443,510, 13 genes, copy number 9: SND1-IT1, LRRC4, MIR593, MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P.
- chr10:65,912,523–67,696,195, 1 gene, copy number 10 (within-gene range 3–10): CTNNA3.
- chr10:66,837,457–68,717,795, 39 genes, copy number 10: AL607023.1, LRRTM3, AL139240.1, RPL7AP51, MIR7151, AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5, MYPN, RN7SKP202, ATOH7, LINC02640, KRT19P4, PBLD, HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA, TMEM14DP, TET1, COX20P1, RPS3AP37, AL513534.2, AL513534.3.
- chr10:68,735,720–68,735,823, 1 gene, copy number 10: Y_RNA.
- chr10:71,711,701–81,137,335, 240 genes, copy number 10–14 (broad region; genes not listed).
- chr10:94,314,907–94,613,905, 4 genes, copy number 16–18 (within-gene range 2–18): AL139124.1, NOC3L, TBC1D12, HELLS.
- chr20:30,278,906–64,313,132, 898 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
